Somatic mutation profile of tumor specimen 0DUVUX from CCDI case PBCLTW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Cerebrum; Age at diagnosis: 1.0 years (354 days).
Specimen 0DUVUX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fd1b806-6d5b-4467-83b8-d2826ee36bac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUVT5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9be95e50-cb10-4687-a239-87e47649653e

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HERC1 | c.8452G>A p.V2818I | Missense Mutation (SNP) | VAF 133/399 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs565203493; called by muse, mutect2, varscan2
- PDGFRA | c.1153A>C p.K385Q | Missense Mutation (SNP) | VAF 447/489 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV57275352; called by muse, mutect2, varscan2
- PDGFRA | c.1154A>T p.K385M | Missense Mutation (SNP) | VAF 450/493 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57264818; called by muse, mutect2, varscan2
- VAMP8 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 202/436 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.217); catalogued as rs759295495, COSV55705188; called by muse, mutect2, varscan2
- BECN2 | c.685C>G p.L229V | Missense Mutation (SNP) | VAF 186/412 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HTR1F | c.371C>A p.A124E | Missense Mutation (SNP) | VAF 212/522 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT43P | n.610G>C | RNA (SNP) | VAF 90/149 reads (60%) | called by muse, mutect2
- ZNF561 | c.*84A>G | 3'UTR (SNP) | VAF 64/123 reads (52%) | called by muse, varscan2
